Somatic mutation profile of tumor specimen TCGA-BA-5556-01A (aliquot TCGA-BA-5556-01A-01D-1512-08) from TCGA case TCGA-BA-5556, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Floor of mouth, NOS; AJCC pathologic stage: Stage II; Tumor grade: G3; Age at diagnosis: 58.7 years (21,444 days).
Specimen TCGA-BA-5556-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 573b1284-434a-4635-a5cc-25aa4c918fe0.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-BA-5556-10A (Blood Derived Normal), aliquot TCGA-BA-5556-10A-01D-1512-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/5c629bb0-edcd-4fdb-8425-42116f5ec3cb

The open-access MAF lists 136 somatic variants for this specimen: 107 protein-altering or splice-affecting, 26 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 96, Silent 26, Nonsense Mutation 5, Frame Shift Ins 4, Intron 2, Splice Site 1, Splice Region 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- HRAS | c.37G>C p.G13R | Missense Mutation (SNP) | VAF 9/49 reads (18%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as rs104894228, CM060018, COSV54236651, COSV54236730, COSV54241641; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- RDH12 | c.146C>T p.T49M | Missense Mutation (SNP) | VAF 18/101 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as rs28940314, CM042103, CM118725, COSV99961791; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ABCA10 | c.1021G>A p.G341R | Missense Mutation (SNP) | VAF 8/87 reads (9%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99288077; called by muse, mutect2
- ABHD15 | c.424G>C p.G142R | Missense Mutation (SNP) | VAF 5/41 reads (12%) | SIFT tolerated (0.11); PolyPhen benign (0.073); catalogued as COSV99975282; called by muse, mutect2
- AC098582.1 | c.1655G>A p.C552Y | Missense Mutation (SNP) | VAF 25/177 reads (14%) | SIFT deleterious (0.03); PolyPhen benign (0.348); catalogued as rs372500127; called by muse, mutect2, varscan2
- ANKFN1 | c.20G>A p.R7K | Missense Mutation (SNP) | VAF 13/146 reads (9%) | SIFT tolerated, low confidence (0.66); PolyPhen benign (0.047); catalogued as rs1341452850, COSV100593217; called by muse, mutect2
- ANKRD30A | c.957C>A p.S319R (on ENST00000611781; = p.S263R on NM_052997.2) | Missense Mutation (SNP) | VAF 8/74 reads (11%) | SIFT tolerated (0.48); PolyPhen benign (0.307); catalogued as rs751663501, COSV100653064, COSV64622500; called by mutect2, varscan2
- APH1A | c.248A>G p.Q83R | Missense Mutation (SNP) | VAF 26/177 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.677); catalogued as COSV99354289; called by muse, mutect2, varscan2
- ATP12A | c.1948T>C p.S650P | Missense Mutation (SNP) | VAF 29/174 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99517157; called by muse, mutect2, varscan2
- ATP6V1H | c.323T>C p.V108A | Missense Mutation (SNP) | VAF 14/66 reads (21%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.759); catalogued as COSV100778616; called by muse, mutect2, varscan2
- ATRX | c.6409G>A p.A2137T | Missense Mutation (SNP) | VAF 29/208 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1557060350, COSV64873095; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ATRX | c.1339G>A p.E447K | Missense Mutation (SNP) | VAF 63/457 reads (14%) | SIFT tolerated, low confidence (0.21); PolyPhen probably damaging (0.98); catalogued as COSV64871127; called by muse, mutect2, varscan2
- B3GALT5 | c.55C>A p.L19I | Missense Mutation (SNP) | VAF 32/275 reads (12%) | SIFT tolerated (0.09); PolyPhen benign (0.018); catalogued as rs769493780, COSV100563303; called by muse, mutect2, varscan2
- BSX | c.439C>T p.L147F | Missense Mutation (SNP) | VAF 57/201 reads (28%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as COSV100545149; called by muse, mutect2, varscan2
- C5orf15 | c.643A>G p.I215V | Missense Mutation (SNP) | VAF 12/83 reads (14%) | SIFT tolerated (1); PolyPhen benign (0.006); catalogued as COSV99198303; called by muse, mutect2, varscan2
- CASP8 | c.1124C>G p.S375* (on ENST00000432109 / NM_033355.3; = p.S392* on NM_001228.4) | Nonsense Mutation (SNP) | VAF 26/142 reads (18%) | catalogued as COSV51851118, COSV51852448; called by muse, mutect2, varscan2
- CNPPD1 | c.893G>T p.C298F | Missense Mutation (SNP) | VAF 20/185 reads (11%) | SIFT tolerated, low confidence (0.37); PolyPhen benign (0); catalogued as COSV99840911; called by muse, mutect2, varscan2
- CNTN5 | c.2707C>G p.L903V | Missense Mutation (SNP) | VAF 8/62 reads (13%) | SIFT tolerated (0.31); PolyPhen benign (0.011); catalogued as COSV99674014; called by muse, mutect2, varscan2
- CPAMD8 | c.3437A>G p.Y1146C (on ENST00000651564; = p.Y1099C on NM_015692.5) | Missense Mutation (SNP) | VAF 5/108 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); catalogued as COSV101488434; called by muse, mutect2
- CRISP2 | c.218G>C p.R73T | Missense Mutation (SNP) | VAF 15/107 reads (14%) | SIFT tolerated (0.06); PolyPhen benign (0.09); catalogued as COSV100188917, COSV59253243; called by muse, mutect2, varscan2
- CYB5R3 | c.86G>A p.R29H | Missense Mutation (SNP) | VAF 7/33 reads (21%) | SIFT deleterious (0.03); PolyPhen benign (0.025); catalogued as rs140159332; called by muse, mutect2, varscan2
- DCAF13 | c.83A>G p.Y28C | Missense Mutation (SNP) | VAF 19/133 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.894); catalogued as rs773394170, COSV99885080; called by muse, mutect2, varscan2
- DHX34 | c.1513G>A p.A505T | Missense Mutation (SNP) | VAF 12/75 reads (16%) | SIFT tolerated (0.16); PolyPhen benign (0.047); catalogued as rs1279763802, COSV100169328; called by muse, mutect2, varscan2
- DIP2B | c.1514A>T p.H505L | Missense Mutation (SNP) | VAF 5/41 reads (12%) | SIFT tolerated (0.93); PolyPhen benign (0.001); catalogued as COSV99998062; called by muse, mutect2
- DMXL2 | c.2620G>C p.E874Q | Missense Mutation (SNP) | VAF 34/269 reads (13%) | SIFT tolerated (0.38); PolyPhen possibly damaging (0.516); catalogued as COSV99196071; called by muse, mutect2, varscan2
- DYRK4 | c.1231A>T p.R411W | Missense Mutation (SNP) | VAF 28/192 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.685); catalogued as COSV99155537; called by muse, mutect2, varscan2
- EIF3B | c.1450C>T p.P484S | Missense Mutation (SNP) | VAF 50/433 reads (12%) | SIFT tolerated (0.1); PolyPhen benign (0.101); catalogued as COSV100703592; called by muse, mutect2, varscan2
- EMSY | c.562T>C p.Y188H | Missense Mutation (SNP) | VAF 50/393 reads (13%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.603); catalogued as COSV100595487; called by muse, mutect2, varscan2
- FAN1 | c.2924A>G p.E975G | Missense Mutation (SNP) | VAF 16/166 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100075957; called by muse, mutect2
- FRY | c.7985C>T p.S2662L | Missense Mutation (SNP) | VAF 50/316 reads (16%) | SIFT deleterious (0.02); PolyPhen benign (0.022); catalogued as rs750020821, COSV66573367; called by muse, mutect2, varscan2
- GATA3 | c.553A>G p.K185E | Missense Mutation (SNP) | VAF 14/123 reads (11%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.556); catalogued as COSV100650856; called by muse, mutect2
- GPR107 | c.854G>A p.R285Q | Missense Mutation (SNP) | VAF 71/262 reads (27%) | SIFT tolerated (0.34); PolyPhen possibly damaging (0.732); catalogued as rs200754726, COSV61277037; called by muse, mutect2, varscan2
- GPRASP1 | c.852G>T p.R284S | Missense Mutation (SNP) | VAF 20/288 reads (7%) | SIFT tolerated (0.15); PolyPhen benign (0.14); catalogued as rs1377871867, COSV100850929; called by muse, mutect2
- GREM2 | c.236G>A p.R79Q | Missense Mutation (SNP) | VAF 8/55 reads (15%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.487); catalogued as COSV58952038, COSV58958071; called by muse, mutect2, varscan2
- HARS2 | c.266G>A p.G89E | Missense Mutation (SNP) | VAF 59/316 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100047556; called by muse, mutect2, varscan2
- KANSL1 | c.2869C>T p.Q957* (on ENST00000574590 / NM_001193465.2; = p.Q958* on NM_015443.4) | Nonsense Mutation (SNP) | VAF 13/91 reads (14%) | catalogued as rs147378906; called by muse, mutect2, varscan2
- KCND1 | c.550G>A p.A184T | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT tolerated (0.45); PolyPhen benign (0.003); catalogued as rs1461767463, COSV54416397, COSV99501697; called by muse, mutect2, varscan2
- KIF24 | c.3870G>A p.A1290= | Splice Region (SNP) | VAF 6/45 reads (13%) | catalogued as rs758074826, COSV52662799; called by muse, mutect2, varscan2
- KIF4A | c.3080C>T p.P1027L | Missense Mutation (SNP) | VAF 20/150 reads (13%) | SIFT tolerated (0.12); PolyPhen benign (0.113); catalogued as COSV100979428, COSV100979577; called by muse, mutect2, varscan2
- KLHL26 | c.1379G>T p.G460V | Missense Mutation (SNP) | VAF 6/38 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV99963033; called by muse, mutect2, varscan2
- LRCH1 | c.725G>C p.C242S | Missense Mutation (SNP) | VAF 8/64 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.124); catalogued as COSV100243358; called by muse, varscan2
- LRP1B | c.13196A>G p.Y4399C | Missense Mutation (SNP) | VAF 17/197 reads (9%) | SIFT tolerated (0.07); PolyPhen benign (0.012); catalogued as COSV101253879, COSV67237998; called by muse, mutect2
- LRP1B | c.5225A>T p.Y1742F | Missense Mutation (SNP) | VAF 14/135 reads (10%) | SIFT tolerated (0.68); PolyPhen benign (0.012); catalogued as COSV101253880; called by muse, mutect2, varscan2
- MARK1 | c.1868G>C p.R623P | Missense Mutation (SNP) | VAF 23/167 reads (14%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.979); catalogued as COSV100857096, COSV65072006; called by muse, mutect2, varscan2
- MED13 | c.3844C>T p.L1282F | Missense Mutation (SNP) | VAF 67/345 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV101180822; called by muse, mutect2, varscan2
- MIPEP | c.200G>A p.G67E | Missense Mutation (SNP) | VAF 28/159 reads (18%) | SIFT tolerated (0.09); PolyPhen benign (0.178); catalogued as COSV101158532; called by muse, mutect2, varscan2
- MOGAT3 | c.155T>A p.L52H | Missense Mutation (SNP) | VAF 7/35 reads (20%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.947); catalogued as COSV99777056; called by muse, mutect2, varscan2
- MON1B | c.1327G>C p.E443Q | Missense Mutation (SNP) | VAF 6/47 reads (13%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.892); catalogued as COSV99941572, COSV99941653; called by muse, mutect2, varscan2
- MUC17 | c.11632A>G p.T3878A | Missense Mutation (SNP) | VAF 43/248 reads (17%) | SIFT tolerated (0.21); PolyPhen benign (0.418); catalogued as COSV100072076; called by muse, mutect2, varscan2
- NAV3 | c.2564G>A p.R855Q | Missense Mutation (SNP) | VAF 21/119 reads (18%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.644); catalogued as rs374085687; called by muse, mutect2, varscan2
- NRF1 | c.163G>T p.D55Y | Missense Mutation (SNP) | VAF 11/156 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.671); catalogued as COSV99781617; called by muse, mutect2
- NRXN2 | c.3742G>A p.E1248K | Missense Mutation (SNP) | VAF 10/84 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.872); catalogued as COSV99632924; called by muse, mutect2, varscan2
- OR14A16 | c.494C>T p.S165F | Missense Mutation (SNP) | VAF 36/192 reads (19%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.832); catalogued as rs1438452611, COSV100713711; called by mutect2, varscan2
- OR1S1 | c.749C>T p.A250V | Missense Mutation (SNP) | VAF 27/146 reads (18%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.874); catalogued as COSV100515295; called by muse, mutect2, varscan2
- OR6T1 | c.818G>T p.G273V | Missense Mutation (SNP) | VAF 79/329 reads (24%) | SIFT tolerated (0.83); PolyPhen benign (0.017); catalogued as COSV100189788; called by muse, mutect2, varscan2
- OR8J3 | c.889G>T p.V297L | Missense Mutation (SNP) | VAF 19/170 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.259); catalogued as COSV100040613; called by muse, mutect2, varscan2
- PCDHGB7 | c.804C>A p.D268E | Missense Mutation (SNP) | VAF 14/87 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99533027; called by muse, mutect2, varscan2
- PHF20L1 | c.2210A>T p.K737I | Missense Mutation (SNP) | VAF 10/192 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.694); catalogued as COSV99620608; called by muse, mutect2
- PHKA2 | c.108C>A p.S36R | Missense Mutation (SNP) | VAF 26/156 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.772); catalogued as COSV101176779; called by muse, mutect2, varscan2
- PNMA3 | c.1228C>T p.R410C | Missense Mutation (SNP) | VAF 19/169 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.629); catalogued as rs782049640, COSV64722539; called by muse, mutect2
- PNMA5 | c.731C>A p.S244Y | Missense Mutation (SNP) | VAF 31/230 reads (13%) | SIFT deleterious (0.05); PolyPhen benign (0.186); catalogued as COSV100721596; called by muse, mutect2, varscan2
- PPIP5K2 | c.985A>T p.K329* | Nonsense Mutation (SNP) | VAF 39/196 reads (20%) | catalogued as COSV100383522; called by muse, mutect2, varscan2
- PPP4R4 | c.1417C>T p.Q473* | Nonsense Mutation (SNP) | VAF 26/188 reads (14%) | catalogued as COSV100428372; called by muse, mutect2, varscan2
- PRDM7 | c.326G>A p.R109K | Missense Mutation (SNP) | VAF 50/369 reads (14%) | SIFT tolerated (0.07); PolyPhen benign (0.294); catalogued as COSV100371099; called by muse, mutect2, varscan2
- PTX3 | c.898C>T p.H300Y | Missense Mutation (SNP) | VAF 12/121 reads (10%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.776); catalogued as COSV99904808; called by muse, mutect2
- RAB40A | c.22G>T p.D8Y | Missense Mutation (SNP) | VAF 12/107 reads (11%) | SIFT deleterious (0.04); PolyPhen benign (0.097); catalogued as COSV100420870; called by muse, mutect2, varscan2
- RBL1 | c.1279A>T p.I427F | Missense Mutation (SNP) | VAF 13/70 reads (19%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.984); catalogued as COSV100726917; called by muse, mutect2, varscan2
- RBM6 | c.1892G>A p.R631K | Missense Mutation (SNP) | VAF 10/72 reads (14%) | SIFT tolerated (0.18); PolyPhen benign (0.007); catalogued as COSV56488607; called by muse, mutect2, varscan2
- REM2 | c.613A>G p.K205E | Missense Mutation (SNP) | VAF 14/93 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.145); catalogued as COSV99944590; called by muse, mutect2, varscan2
- RPH3AL | c.253C>T p.R85W | Missense Mutation (SNP) | VAF 5/51 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.901); catalogued as rs758943991, COSV58745184; called by muse, mutect2
- RPS6KA3 | c.501A>T p.E167D | Missense Mutation (SNP) | VAF 7/93 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV101084193; called by muse, mutect2
- RYR3 | c.8021C>G p.S2674C (on ENST00000389232; = p.S2675C on NM_001036.6) | Missense Mutation (SNP) | VAF 19/131 reads (15%) | SIFT tolerated (0.23); PolyPhen probably damaging (0.998); catalogued as COSV101212142, COSV66808286; called by muse, mutect2, varscan2
- S100B | c.111C>G p.I37M | Missense Mutation (SNP) | VAF 12/95 reads (13%) | SIFT tolerated (0.31); PolyPhen benign (0.129); catalogued as COSV99388297; called by muse, mutect2, varscan2
- SEMA3A | c.1658C>T p.T553I | Missense Mutation (SNP) | VAF 20/151 reads (13%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.474); catalogued as COSV99545672; called by muse, mutect2, varscan2
- SLC10A2 | c.379G>A p.V127I | Missense Mutation (SNP) | VAF 15/105 reads (14%) | SIFT tolerated (1); PolyPhen benign (0.012); catalogued as rs150843319; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SLC12A5 | c.2044C>T p.R682C (on ENST00000454036 / NM_001134771.2; = p.R659C on NM_020708.5) | Missense Mutation (SNP) | VAF 4/36 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as rs1173713421, COSV54788580; ClinVar: uncertain significance; called by muse, mutect2
- SLC38A8 | c.937G>A p.V313M | Missense Mutation (SNP) | VAF 11/70 reads (16%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.888); catalogued as rs373901370; called by muse, mutect2, varscan2
- SLC4A1AP | c.1099A>G p.I367V | Missense Mutation (SNP) | VAF 28/157 reads (18%) | SIFT deleterious (0.04); PolyPhen benign (0.053); catalogued as COSV100389212; called by muse, mutect2, varscan2
- SLC8A1 | c.1408G>A p.D470N | Missense Mutation (SNP) | VAF 12/124 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.099); catalogued as COSV60470987; called by muse, mutect2
- SLITRK3 | c.365A>G p.N122S | Missense Mutation (SNP) | VAF 22/134 reads (16%) | SIFT tolerated (0.11); PolyPhen benign (0); catalogued as rs780971539, COSV99578721; called by muse, mutect2, varscan2
- ST18 | c.2108C>T p.A703V | Missense Mutation (SNP) | VAF 27/242 reads (11%) | SIFT tolerated (1); PolyPhen benign (0.011); catalogued as COSV99388649; called by muse, mutect2, varscan2
- TASOR | c.1514-1G>T p.X505_splice (on ENST00000355628 / NM_001365636.2; = p.X109_splice on NM_015224.3) | Splice Site (SNP) | VAF 20/113 reads (18%) | catalogued as COSV100843387; called by muse, mutect2, varscan2
- THRAP3 | c.1627G>T p.E543* | Nonsense Mutation (SNP) | VAF 25/247 reads (10%) | catalogued as COSV100663247, COSV63568093; called by muse, mutect2, varscan2
- TLK2 | c.1697A>G p.E566G (on ENST00000326270 / NM_001284333.2; = p.E544G on NM_006852.6 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 19/121 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100408812; called by muse, mutect2, varscan2
- TOM1L2 | c.425A>T p.E142V (on ENST00000379504 / NM_001350333.2; = p.E92V on NM_001033551.3) | Missense Mutation (SNP) | VAF 24/260 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.931); catalogued as COSV100540924; called by muse, mutect2
- TRIM37 | c.55A>G p.M19V | Missense Mutation (SNP) | VAF 16/112 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.782); catalogued as rs750613096, COSV99232434; called by muse, mutect2, varscan2
- TYRO3 | c.2363A>T p.N788I | Missense Mutation (SNP) | VAF 9/127 reads (7%) | SIFT tolerated (0.15); PolyPhen benign (0.001); catalogued as COSV99777327; called by muse, mutect2
- USH2A | c.9947A>T p.N3316I | Missense Mutation (SNP) | VAF 37/177 reads (21%) | SIFT tolerated (0.21); PolyPhen benign (0); catalogued as COSV100230753; called by muse, mutect2, varscan2
- VPS13B | c.4337A>T p.H1446L | Missense Mutation (SNP) | VAF 41/227 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs371961155, COSV100661081; called by muse, mutect2, varscan2
- VPS26C | c.326A>G p.Y109C | Missense Mutation (SNP) | VAF 7/193 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99898335; called by muse, mutect2
- WDFY2 | c.632A>T p.Q211L | Missense Mutation (SNP) | VAF 50/292 reads (17%) | SIFT deleterious (0.05); PolyPhen benign (0.053); catalogued as COSV99986894; called by muse, mutect2, varscan2
- WDR44 | c.2701G>A p.A901T | Missense Mutation (SNP) | VAF 19/132 reads (14%) | SIFT tolerated (0.1); PolyPhen benign (0.041); catalogued as COSV99561304; called by muse, mutect2, varscan2
- WIPF2 | c.677C>T p.A226V | Missense Mutation (SNP) | VAF 33/274 reads (12%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.587); catalogued as rs770354097, COSV100063360; called by muse, mutect2, varscan2
- YTHDC1 | c.1769A>G p.N590S (on ENST00000344157 / NM_001031732.4; = p.N572S on NM_133370.4) | Missense Mutation (SNP) | VAF 8/82 reads (10%) | SIFT tolerated (0.11); PolyPhen benign (0.063); catalogued as rs1242869594, COSV100704626; called by muse, mutect2
- ZC3H15 | c.219C>G p.D73E | Missense Mutation (SNP) | VAF 6/69 reads (9%) | SIFT tolerated (0.49); PolyPhen benign (0.003); catalogued as COSV100552001; called by muse, mutect2, varscan2
- ZIC4 | c.98A>C p.Q33P | Missense Mutation (SNP) | VAF 12/56 reads (21%) | SIFT tolerated, low confidence (0.3); PolyPhen benign (0); catalogued as COSV101267865; called by muse, mutect2, varscan2
- ZNF181 | c.475A>G p.I159V | Missense Mutation (SNP) | VAF 25/137 reads (18%) | SIFT tolerated (0.18); PolyPhen benign (0.001); catalogued as COSV101106211; called by muse, mutect2, varscan2
- ZNF334 | c.881A>T p.E294V | Missense Mutation (SNP) | VAF 55/313 reads (18%) | SIFT tolerated (0.09); PolyPhen benign (0.14); catalogued as COSV100748995; called by muse, mutect2, varscan2
- ZNF791 | c.111C>G p.F37L | Missense Mutation (SNP) | VAF 18/134 reads (13%) | SIFT tolerated (0.26); PolyPhen benign (0.007); catalogued as rs1199467503, COSV100589045, COSV104413081; called by muse, mutect2, varscan2
- ZSCAN10 | c.884C>T p.A295V (on ENST00000252463; = p.A350V on NM_032805.3) | Missense Mutation (SNP) | VAF 8/161 reads (5%) | SIFT deleterious (0.01); PolyPhen benign (0.065); catalogued as rs1185206483, COSV99373872; called by muse, mutect2
- AJUBA | c.909dup p.I304Dfs*2 | Frame Shift Ins (INS) | VAF 6/51 reads (12%) | called by mutect2, pindel, varscan2
- HLA-A | c.794T>C p.F265S | Missense Mutation (SNP) | VAF 8/112 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); called by muse, varscan2
- MYCBP2 | c.13749dup p.D4584* (on ENST00000357337; = p.D4622* on NM_015057.5) | Frame Shift Ins (INS) | VAF 17/151 reads (11%) | called by mutect2, pindel, varscan2
- SUPT20HL2 | c.203T>A p.L68H | Missense Mutation (SNP) | VAF 22/224 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, varscan2
- TP53BP1 | c.5471dup p.C1825Lfs*9 | Frame Shift Ins (INS) | VAF 14/129 reads (11%) | called by mutect2, varscan2
- TPTE | c.923A>T p.N308I (on ENST00000618007 / NM_199261.4; = p.N290I on NM_199259.4) | Missense Mutation (SNP) | VAF 25/551 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2
- WWP1 | c.2410dup p.M804Nfs*5 | Frame Shift Ins (INS) | VAF 29/210 reads (14%) | called by mutect2, pindel, varscan2
- ANPEP | c.2790C>T p.F930= | Silent (SNP) | VAF 18/275 reads (7%) | catalogued as rs145116014; called by muse, mutect2
- APP | c.1971G>A p.G657= | Silent (SNP) | VAF 35/298 reads (12%) | catalogued as rs141559720; called by muse, mutect2, varscan2
- CNR2 | c.39C>G p.S13= | Silent (SNP) | VAF 30/254 reads (12%) | catalogued as COSV100991256; called by muse, mutect2, varscan2
- DNAJB7 | c.801G>A p.E267= | Silent (SNP) | VAF 25/169 reads (15%) | catalogued as COSV53421847; called by muse, mutect2, varscan2
- EIF3B | c.1449G>T p.V483= | Silent (SNP) | VAF 52/433 reads (12%) | catalogued as COSV100703591; called by muse, mutect2, varscan2
- FRMPD4 | c.528C>A p.V176= | Silent (SNP) | VAF 15/115 reads (13%) | catalogued as COSV101042351; called by muse, mutect2, varscan2
- GPATCH2L | c.1002T>G p.T334= | Silent (SNP) | VAF 28/196 reads (14%) | catalogued as COSV99833432; called by muse, mutect2, varscan2
- HNF1A | c.534C>T p.T178= | Silent (SNP) | VAF 8/52 reads (15%) | catalogued as COSV99982239; called by muse, mutect2, varscan2
- ITGA9 | c.912C>T p.F304= | Silent (SNP) | VAF 16/104 reads (15%) | catalogued as rs747663933, COSV53250023; called by muse, mutect2, varscan2
- LRRN3 | c.91C>A p.R31= | Silent (SNP) | VAF 22/180 reads (12%) | catalogued as COSV57818597; called by muse, mutect2, varscan2
- MADD | c.3879A>G p.K1293= | Silent (SNP) | VAF 43/248 reads (17%) | catalogued as COSV100211142; called by muse, mutect2, varscan2
- MED12 | c.3978T>C p.Y1326= | Silent (SNP) | VAF 5/39 reads (13%) | catalogued as COSV100376634; called by muse, mutect2, varscan2
- MROH2B | c.2826C>T p.T942= | Silent (SNP) | VAF 7/19 reads (37%) | catalogued as COSV101270574; called by muse, mutect2, varscan2
- MUC2 | c.3426C>T p.F1142= | Silent (SNP) | VAF 3/24 reads (13%) | catalogued as rs752920531; called by muse, mutect2
- NPAP1 | c.2832T>C p.G944= | Silent (SNP) | VAF 27/155 reads (17%) | catalogued as COSV100274900; called by muse, mutect2, varscan2
- OPA3 | c.235C>T p.L79= | Silent (SNP) | VAF 22/187 reads (12%) | catalogued as COSV99840867; called by muse, mutect2, varscan2
- PGAM4 | c.627C>T p.N209= | Silent (SNP) | VAF 15/324 reads (5%) | catalogued as COSV100430416; called by muse, mutect2
- PLS1 | c.159C>T p.R53= | Silent (SNP) | VAF 28/237 reads (12%) | catalogued as rs371894541; called by muse, mutect2, varscan2
- PODN | c.939C>T p.R313= (on ENST00000395871; = p.R265= on NM_153703.5 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 46/290 reads (16%) | catalogued as rs138179023, COSV100439598; called by muse, mutect2, varscan2
- RERG | c.300C>T p.N100= | Silent (SNP) | VAF 95/542 reads (18%) | catalogued as rs749923403, COSV99917196; called by muse, mutect2, varscan2
- RTCA | c.303C>T p.L101= | Silent (SNP) | VAF 48/361 reads (13%) | catalogued as COSV99559628; called by muse, mutect2, varscan2
- SCAF11 | c.4164A>G p.K1388= | Silent (SNP) | VAF 21/123 reads (17%) | catalogued as COSV101014120; called by muse, mutect2, varscan2
- SERTAD1 | c.582C>G p.L194= | Silent (SNP) | VAF 7/37 reads (19%) | catalogued as COSV100781670; called by muse, mutect2, varscan2
- SLC39A8 | c.753C>T p.I251= | Silent (SNP) | VAF 9/109 reads (8%) | catalogued as COSV100765660; called by muse, mutect2, varscan2
- SLITRK5 | c.1980G>A p.S660= | Silent (SNP) | VAF 9/66 reads (14%) | catalogued as COSV61522773; called by muse, mutect2, varscan2
- STXBP3 | c.1482A>G p.E494= | Silent (SNP) | VAF 15/128 reads (12%) | catalogued as COSV100893904; called by muse, mutect2, varscan2
- DMD | c.8218-775A>T | Intron (SNP) | VAF 5/55 reads (9%) | catalogued as COSV100626219; called by muse, mutect2, varscan2
- MIR506 | n.20C>A | RNA (SNP) | VAF 28/195 reads (14%) | called by muse, mutect2, varscan2
- STXBP1 | c.1702+1808G>A | Intron (SNP) | VAF 14/68 reads (21%) | catalogued as COSV100964533; called by muse, mutect2, varscan2
